Gene-level copy-number profile of specimen HCM-SANG-0298-C15-85A from HCMI case HCM-SANG-0298-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0298-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4ca72743-8348-442d-b441-fcdf0ad99f53.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0298-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/17c98d23-443e-49d8-ab12-4c411c12751e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,560; copy number 2: 24,246; copy number 3: 22,669; copy number 4: 5,825; copy number 5: 2,427; copy number 6: 583; copy number 7: 698; copy number 8: 898.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,596 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:88,205,115–89,338,528, 15 genes, copy number 8: SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47.
- chr7:92,457,564–92,495,601, 1 gene, copy number 7 (within-gene range 3–7): AC007566.1.
- chr7:92,487,020–93,574,730, 17 genes, copy number 7–8: PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489.
- chr7:97,598,933–100,928,540, 148 genes, copy number 7 (broad region; genes not listed).
- chr10:79,904,898–80,535,942, 31 genes, copy number 7–8: AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1.
- chr13:70,107,213–114,337,626, 515 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:30,278,906–64,327,972, 869 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,048. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
